Surgical pathology report (de-identified scan), TCGA case TCGA-GJ-A6C0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GJ-A6C0-01A (Primary Tumor).

[page 1 of 3]
Clinical Information:

year old female presented with liver mass, work-up showed hepatocellular carcinoma

Operative Procedure:

Right hepatectomy, chole

Pre-Operative Diagnosis:

Hepatocellular carcinoma

Specimen Received:

- A: Gallbladder
- B: Right liver
- C: Right colon and distal ileum
- D: Small bowel

Final Pathologic Diagnosis:

A. Gallbladder, cholecystectomy:

Cholelithiasis with prominent Rokitansky-Aschoff sinuses.

B. Liver, right, hepatectomy:

Hepatocellular carcinoma, moderately differentiated, see note A.

Negative for cirrhosis.

Scattered PAS positive intracellular globules in non-neoplastic hepatocytes, see note B.

Specimen: Liver and gallbladder
Procedure: Partial hepatectomy
Tumor histologic type: Hepatocellular carcinoma
Tumor size: 14.2 x 9.5 x 16.5 cm
Tumor focality: Right
Number of tumors: One
Histologic type: Hepatocellular carcinoma
Histologic grade: Moderately differentiated
Tumor extension: Tumor confined to liver (close [1mm]) from capsular surface but no penetration identified)

Margins:

Parenchymal: Uninvolved

If uninvolved, distance of invasive carcinoma from closest margin: 10 mm from the inked parenchymal margin (intraoperative gross diagnosis confirmed).

Lymph-vascular invasion:

Macroscopic venous (large vessel) invasion: Not identified

ICD-O-3 NOS
Carcinoma, Hepatocellular
8170/3
Site Liver C22.0
JAW 5/24/13

[page 2 of 3]
Microscopic (small vessel) invasion: Present

Pathologic staging: (pTMN)

TNM descriptors: None

Primary tumor: pT2

Regional lymph nodes: Not applicable

Distant metastasis: Not applicable

C. Right colon and distal ileum, resection:

Ulceration with perforation.

Acute peritonitis.

Fibrous adhesions.

D. Small bowel, resection:

Fibrous adhesions with acute peritonitis.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The presence of PAS positive globules in hepatic cells could indicate the patient is a carrier of an alpha-1-antitrypsin gene mutation.

Intraoperative Consult Diagnosis:

FSB: Right liver (gross portion only):

1 cm from inked margin.

TAT: 5 mins.

Gross Description:

The specimen is received in four parts, each labeled with the patient name

Specimen A is received in a formalin filled container, and is additionally labeled, "gallbladder." The specimen is grossly consistent with a gallbladder with dimensions of 8.5 x 3.3 x 2.4 cm. The serosal surface has brachial hemorrhage and there is some adherent clotted blood. Opening the specimen reveals it to be filled with multifaceted stones and dark green viscid bile. The wall of the gallbladder is edematous but the mucosa has a uniform thickness of 0.2 cm. Representative sections through the wall and the cystic duct margin are included in a single cassette A.

The specimen is consistent with a partial hepatectomy that has dimensions of 16.7 x 16.5 x 10.2 cm. The serosal surface is heterogeneously dark brown and light tan. A whitish mass could be seen protruding from the parenchyma abutting the capsule. The surgical margin is inked black. The specimen is bread loafed to reveal a large nodular white mass which has dimensions of 14.2 x 9.5 x 16.5 cm. The mass has both cystic and solid areas. The cystic areas appear to be hemorrhagic. At its closest point the mass comes to within 1.5 cm of the inked margin and abuts the capsule. There are no designated vessels or ducts.

[page 3 of 3]
Representative sections are submitted as follows:

- B1,2 mass to inked margin;
- B3,4 mass to capsule;
- B5,6 uninvolved parenchyma.
- B7-9 interface sections

The specimen is grossly consistent with a segment of bowel that has a large bowel with a small segment of small bowel attached. The large bowel has a length of 19 cm and a diameter that ranges from 1.5 cm to 5.5 cm. The attached small bowel has a length of 6.5 cm and a diameter that ranges from 3 cm to 1.5 cm. There is a defect in the large bowel which is leaking fecal material. This defect has a diameter of 1.2 cm and is located 9.8 cm from the proximal margin. There is a moderate amount of attached to the serosal surface that has dimensions of 24 x 11.5 x 3.5 cm. The fat and serosa are erythematous with adherent fibrinopurulent adhesions. Representative sections are submitted as follows:

- C1 proximal margin;
- C2 distal margin;
- C3 defect;
- C4 ileocecal valve.

The mesenteric fat is searched for lymph nodes. Multiple potential ones are found. Representative sections are as follows:

- C5,6 potential whole lymph nodes.

The fat is submitted in cassettes C5 and 6.

Specimen D is received in a formalin filled container additionally labeled, "small bowel." The specimen is consistent with a segment of small bowel that is 3.5 cm in length with an average diameter that ranges from 1.3 to 1.8 cm. Both ends are stapled shut. There is a suture on the specimen near a possible defect. Representative sections are submitted as follows:

- D1 representative sections from each stapled margin;
- D2-3 through defect.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: Age: Gender: F

Source: NCI Genomic Data Commons file c0dc3746-263a-45c0-9fa4-f1f87c444c6d (TCGA-GJ-A6C0.D9F106D7-C163-46C5-8DDC-FF60ED1CF17B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).